Somatic mutation profile of tumor specimen TCGA-55-8616-01A (aliquot TCGA-55-8616-01A-11D-2393-08) from TCGA case TCGA-55-8616, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 58.1 years (21,225 days).
Specimen TCGA-55-8616-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcf24b26-a9ba-4523-bd10-56a5c6bd3a70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8616-10A (Blood Derived Normal), aliquot TCGA-55-8616-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9337f7b-8de7-4bbf-b999-11897ddf1156

The open-access MAF lists 536 somatic variants for this specimen: 405 protein-altering or splice-affecting, 117 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 348, Silent 117, Nonsense Mutation 28, Splice Site 13, Intron 8, Frame Shift Del 6, Frame Shift Ins 6, Splice Region 3, RNA 2, 5'UTR 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PAH | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796064503, CM1111369, COSV100187666; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 50/96 reads (52%) | hotspot (GDC flag); catalogued as rs757274881, CM102352, COSV52662339, COSV52764890, COSV53424649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3698G>A p.G1233E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100228565; called by muse, mutect2, varscan2
- ABHD16B | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1017133303, COSV99410534; called by muse, mutect2, varscan2
- ADAM11 | c.1140G>T p.M380I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV99567135; called by muse, mutect2, varscan2
- ADAM22 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV99715845; called by muse, mutect2, varscan2
- ADAMTS2 | c.2948C>A p.P983H | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV99281046; called by muse, mutect2, varscan2
- ADARB2 | c.1617G>C p.Q539H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV101186619; called by muse, mutect2
- ADARB2 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.467); catalogued as COSV101186620; called by muse, mutect2
- ADCY2 | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 78/124 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV100601879, COSV57864504; called by muse, mutect2, varscan2
- ADCY8 | c.2882G>C p.R961P | Missense Mutation (SNP) | VAF 96/160 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV99650885; called by muse, mutect2, varscan2
- ADGRB3 | c.3492C>A p.N1164K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as COSV99483774; called by muse, mutect2, varscan2
- AFDN | c.1381G>T p.V461L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as COSV60053781; called by muse, mutect2, varscan2
- AGA | c.807-1G>T p.X269_splice | Splice Site (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99219377; called by muse, mutect2, varscan2
- AGTPBP1 | c.2003A>T p.Y668F (on ENST00000357081 / NM_001330701.2; = p.Y628F on NM_015239.2) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.185); catalogued as COSV100429282; called by muse, mutect2, varscan2
- AJAP1 | c.920G>T p.C307F | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100981503; called by muse, mutect2, varscan2
- ANAPC2 | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.133); catalogued as COSV100118913, COSV60569643, COSV60572899; called by muse, mutect2, varscan2
- ANK2 | c.6553G>T p.D2185Y | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV99999950; called by muse, mutect2, varscan2
- ANO3 | c.1451C>T p.T484I | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV99880837; called by muse, mutect2, varscan2
- ARHGAP25 | c.1541G>A p.G514E (on ENST00000409202 / NM_001007231.3; = p.G506E on NM_014882.3) | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99771099; called by muse, mutect2, varscan2
- ARHGAP30 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.546); catalogued as rs143165869; called by muse, mutect2, varscan2
- ARHGEF17 | c.1611G>T p.L537F | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99734947; called by muse, mutect2, varscan2
- ARHGEF17 | c.4198C>T p.P1400S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.945); catalogued as rs750522045, COSV99734949; called by muse, mutect2, varscan2
- ARMCX3 | c.526G>C p.D176H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); catalogued as COSV100362188; called by muse, mutect2, varscan2
- ASB3 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55075909; called by muse, mutect2, varscan2
- ASXL3 | c.4852G>A p.G1618R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV52477882; called by muse, mutect2, varscan2
- ATOH1 | c.859G>T p.V287L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100024440; called by muse, mutect2, varscan2
- ATP10B | c.1073T>A p.L358H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as COSV100469107; called by muse, mutect2, varscan2
- ATP2A3 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs144159559; called by muse, mutect2
- ATP6V0D1 | c.993G>T p.W331C | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99340958; called by muse, mutect2, varscan2
- ATP7A | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 78/236 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV100430296; called by muse, mutect2, varscan2
- ATXN2 | c.1934G>T p.S645I (on ENST00000550104; = p.S485I on NM_002973.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); catalogued as COSV101112597; called by muse, mutect2, varscan2
- BARD1 | c.1448A>G p.H483R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.161); catalogued as rs587781874, COSV99637958; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BCLAF3 | c.507G>T p.W169C | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100503228; called by muse, mutect2, varscan2
- BIRC5 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100051240; called by muse, mutect2
- BNC1 | c.2922C>A p.N974K | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100596932; called by muse, mutect2, varscan2
- BNC1 | c.2561C>A p.T854N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100596933; called by muse, mutect2, varscan2
- BRD7 | c.1583G>A p.G528D | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.517); catalogued as COSV54268121; called by muse, mutect2
- BRDT | c.2244G>T p.Q748H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV100746151; called by muse, mutect2, varscan2
- BTG1 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99755326; called by muse, mutect2, varscan2
- C19orf18 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100071653; called by muse, mutect2, varscan2
- C4orf50 | c.154G>T p.E52* (on ENST00000324058; = p.E1284* on NM_001364689.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100135610, COSV100136023; called by muse, mutect2, varscan2
- CACNA1E | c.4757T>A p.L1586H | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100701318; called by muse, mutect2, varscan2
- CAPN10 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 35/132 reads (27%) | catalogued as COSV99549973; called by muse, mutect2, varscan2
- CARD11 | c.1451C>A p.P484H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV100829086; called by muse, mutect2, varscan2
- CASKIN1 | c.3322G>A p.A1108T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1310637070, COSV100399109; called by muse, mutect2, varscan2
- CATSPERD | c.1893G>T p.W631C | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100486666; called by muse, mutect2
- CCDC40 | c.2549A>T p.N850I | Missense Mutation (SNP) | VAF 62/94 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100884230; called by muse, mutect2, varscan2
- CD207 | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV101338531, COSV101338546; called by muse, mutect2, varscan2
- CDH10 | c.2296C>G p.R766G | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100050202, COSV52579639, COSV52582699; called by muse, mutect2, varscan2
- CDH10 | c.1985G>T p.G662V | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100050204, COSV52598917; called by muse, mutect2, varscan2
- CDH10 | c.690A>T p.R230S | Missense Mutation (SNP) | VAF 92/161 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV52580969; called by muse, mutect2, varscan2
- CDH12 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV66393861; called by muse, mutect2
- CELF4 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100611162; called by muse, mutect2, varscan2
- CEP170 | c.924G>T p.K308N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.432); catalogued as COSV100316482; called by mutect2, varscan2
- CHD3 | c.2928G>T p.M976I | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV100390769; called by muse, mutect2, varscan2
- CHL1 | c.1092G>T p.W364C (on ENST00000397491 / NM_001253387.1; = p.W380C on NM_006614.4) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99850200; called by muse, mutect2, varscan2
- CHRM1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100186113; called by muse, mutect2, varscan2
- CHRNA10 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99167121; called by muse, mutect2, varscan2
- CLCN1 | c.1652G>T p.G551V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM101110, COSV100577742; called by muse, varscan2
- CLCN1 | c.1722G>T p.Q574H | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV100577744; called by muse, varscan2
- CLDN2 | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV61021035; called by muse, mutect2, varscan2
- CNTNAP1 | c.1162C>A p.R388S | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs755070825, COSV99226140, COSV99226997; called by muse, mutect2, varscan2
- CNTNAP2 | c.882G>T p.R294S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as COSV100663087, COSV100669189; called by muse, mutect2, varscan2
- CNTNAP5 | c.3412C>A p.L1138I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV101443090; called by muse, mutect2, varscan2
- COL11A1 | c.4286G>T p.G1429V | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62204904; called by muse, mutect2, varscan2
- COL11A1 | c.4285G>A p.G1429R | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100615302; called by muse, mutect2, varscan2
- COL15A1 | c.3302C>A p.P1101Q | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV100897439; called by muse, mutect2, varscan2
- COL1A2 | c.2233G>T p.G745W | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99798727; called by muse, mutect2, varscan2
- COL20A1 | c.1611G>T p.Q537H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.859); catalogued as COSV100489978; called by muse, mutect2, varscan2
- COL2A1 | c.1862G>T p.G621V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100475620; called by muse, mutect2, varscan2
- COL4A6 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as COSV100563424; called by muse, mutect2, varscan2
- CORIN | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.108); catalogued as rs1260813872, COSV99902965; called by muse, mutect2, varscan2
- CORIN | c.813G>T p.R271S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99902966; called by muse, mutect2, varscan2
- CPS1 | c.4414del p.L1472Ffs*48 | Frame Shift Del (DEL) | VAF 50/216 reads (23%) | catalogued as rs755682125; called by mutect2, pindel, varscan2
- CPXM1 | c.2034C>A p.Y678* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV101013682; called by muse, mutect2, varscan2
- CREBBP | c.3670G>T p.D1224Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99062749, COSV99268705; called by muse, mutect2
- CTC1 | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100236163; called by muse, mutect2, varscan2
- CTNNA2 | c.172C>A p.H58N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.341); catalogued as COSV100781876, COSV63594113; called by muse, mutect2, varscan2
- CTNNA2 | c.2034G>C p.E678D | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.377); catalogued as COSV100559536; called by muse, mutect2, varscan2
- CTNND2 | c.2899C>A p.L967M | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100472376; called by muse, mutect2, varscan2
- CUBN | c.9380G>T p.S3127I | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.221); catalogued as COSV100912108, COSV100912328; called by muse, mutect2, varscan2
- CUL4B | c.395C>G p.A132G | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.077); catalogued as rs969827040, COSV100340182; called by muse, mutect2, varscan2
- CUX2 | c.3970G>T p.G1324C | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV99918727; called by muse, mutect2, varscan2
- CYP26A1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99814585; called by muse, mutect2, varscan2
- DCAF12L2 | c.932G>T p.C311F | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100758472; called by muse, varscan2
- DCAF12L2 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.786); catalogued as rs771293147, COSV63584716; called by muse, mutect2, varscan2
- DCAF4L2 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100150524; called by muse, mutect2
- DCHS1 | c.8860G>T p.A2954S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV100197191; called by muse, mutect2
- DECR2 | c.760A>G p.S254G | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99557003; called by muse, mutect2, varscan2
- DGCR8 | c.1936G>T p.G646W | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100707817; called by muse, mutect2, varscan2
- DNAAF3 | c.730G>A p.D244N (on ENST00000524407 / NM_001256715.2; = p.D291N on NM_178837.4) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1461569802, COSV100787857; called by muse, mutect2
- DNAJC1 | c.660T>A p.H220Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV100977990; called by muse, mutect2, varscan2
- DNAJC5B | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52535665; called by muse, mutect2
- DRD2 | c.560C>A p.P187Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60755303, COSV60759749; called by muse, mutect2
- DRP2 | c.1325T>G p.M442R | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV100871802; called by muse, mutect2, varscan2
- DYNC1H1 | c.9661G>T p.D3221Y | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV100794506; called by muse, mutect2, varscan2
- EDN3 | c.607C>A p.Q203K (on ENST00000337938 / NM_001302455.2; = p.N214K on NM_207032.3) | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.026); catalogued as COSV100284805; called by muse, mutect2, varscan2
- EFCAB1 | c.116T>A p.V39E | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as COSV100030601; called by muse, mutect2, varscan2
- EIF3K | c.375G>T p.M125I | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99942899; called by muse, mutect2, varscan2
- EIF4G2 | c.2059C>T p.R687* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100379384; called by mutect2, varscan2
- EMX1 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV99252367; called by muse, mutect2, varscan2
- EPB41L3 | c.2168A>T p.K723I | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV100548227; called by muse, mutect2, varscan2
- EPB42 | c.1337A>T p.E446V (on ENST00000441366 / NM_001114134.2; = p.E476V on NM_000119.3) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV100281798; called by muse, mutect2, varscan2
- EPC1 | c.1514C>T p.T505I | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as COSV99552577; called by muse, mutect2, varscan2
- EPHA5 | c.660C>A p.C220* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99896515; called by muse, mutect2, varscan2
- ERCC6 | c.2710-1G>C p.X904_splice | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100875707; called by muse, mutect2, varscan2
- ERICH3 | c.4196C>A p.A1399D | Missense Mutation (SNP) | VAF 95/170 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV100443504; called by muse, mutect2, varscan2
- ETFB | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as CD155870, COSV100495520; called by muse, mutect2, varscan2
- EVC2 | c.2911C>T p.Q971* | Nonsense Mutation (SNP) | VAF 24/74 reads (32%) | catalogued as COSV100185127; called by muse, mutect2, varscan2
- FAM47C | c.1935G>T p.E645D | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.279); catalogued as COSV100792312; called by muse, mutect2, varscan2
- FAT2 | c.3280C>A p.P1094T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV99941809; called by muse, varscan2
- FAT3 | c.13605C>A p.S4535R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV53177796; called by muse, mutect2, varscan2
- FBXO40 | c.778G>T p.G260* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100572952; called by muse, mutect2, varscan2
- FGF10 | c.315C>G p.N105K | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV99240127; called by muse, mutect2, varscan2
- FIGNL2 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs753640698; called by muse, mutect2, varscan2
- FLG | c.10511C>T p.S3504L | Missense Mutation (SNP) | VAF 40/463 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV64251559; called by muse, mutect2
- FLNA | c.1684G>T p.G562W | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100774316, COSV61044159; called by muse, mutect2, varscan2
- FOXO4 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV100446780; called by muse, mutect2, varscan2
- FRMPD4 | c.3620A>G p.H1207R | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV101042200; called by muse, mutect2, varscan2
- FRYL | c.3915G>T p.M1305I | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV99975892; called by muse, mutect2, varscan2
- FUT8 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV100651090; called by muse, mutect2, varscan2
- GAB4 | c.275G>C p.R92P | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68753050, COSV68754617; called by muse, mutect2, varscan2
- GABRB1 | c.1242C>A p.Y414* | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | catalogued as COSV54979613, COSV99780315; called by muse, mutect2
- GAL3ST1 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100142929; called by muse, mutect2, varscan2
- GALNTL6 | c.368C>A p.P123Q | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101487676; called by muse, mutect2, varscan2
- GALNTL6 | c.1617C>A p.N539K | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101560125; called by muse, mutect2, varscan2
- GALT | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66593377; called by muse, mutect2, varscan2
- GDF10 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs782520978; called by muse, mutect2
- GIMAP7 | c.389T>A p.L130* | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as COSV100543582; called by muse, mutect2, varscan2
- GIP | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as COSV100656907; called by muse, mutect2, varscan2
- GLP2R | c.1003G>T p.G335W | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV52324187; called by muse, mutect2, varscan2
- GMIP | c.1435G>T p.G479C | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99179090; called by muse, mutect2, varscan2
- GPR161 | c.1146G>T p.Q382H | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT tolerated (0.33); PolyPhen benign (0.135); catalogued as COSV99606262; called by muse, mutect2, varscan2
- GPR179 | c.5992G>A p.V1998M (on ENST00000621958; = p.V1997M on NM_001004334.4) | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.342); catalogued as rs563623827; called by muse, mutect2, varscan2
- GPR50 | c.384C>A p.C128* | Nonsense Mutation (SNP) | VAF 20/126 reads (16%) | catalogued as COSV99505709; called by muse, mutect2, varscan2
- GPSM2 | c.275C>A p.A92E | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99915046; called by muse, mutect2, varscan2
- GRIN2A | c.415-1G>T p.X139_splice | Splice Site (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100408474, COSV58058435; called by muse, mutect2, varscan2
- GRM8 | c.1409G>T p.R470L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs148874550, COSV58872575; called by muse, mutect2, varscan2
- GSC | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs759761613, COSV99450051; called by muse, mutect2, varscan2
- GTF2H1 | c.837+1G>T p.X279_splice | Splice Site (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99786323; called by muse, varscan2
- GUCA1A | c.390G>T p.M130I | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99273823; called by muse, mutect2, varscan2
- H2BC9 | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99769025; called by muse, mutect2, varscan2
- HAND2 | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100854144; called by muse, varscan2
- HAS1 | c.844A>T p.S282C | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV99708225; called by muse, mutect2, varscan2
- HEPH | c.1130G>T p.G377V (on ENST00000343002; = p.G110V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs373443837, COSV100294182; called by muse, mutect2, varscan2
- HERC1 | c.13688G>T p.R4563M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV101496363; called by muse, varscan2
- HERC2 | c.13568C>T p.A4523V | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.277); catalogued as COSV99871286; called by muse, mutect2, varscan2
- HERC2 | c.9109C>T p.R3037W | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs756736818; called by muse, mutect2
- HOXA5 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV56072480, COSV99762104; called by muse, varscan2
- HSPA12A | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV100979717; called by muse, mutect2, varscan2
- HTR1B | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV100885340; called by muse, mutect2
- HUWE1 | c.11210C>A p.T3737K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as COSV53357729, COSV99470786; called by muse, varscan2
- IDH3G | c.1131G>T p.Q377H | Missense Mutation (SNP) | VAF 48/289 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV54206396; called by muse, mutect2, varscan2
- IFTAP | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100530948; called by muse, mutect2, varscan2
- IGSF1 | c.1999G>C p.A667P | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.855); catalogued as COSV100811847; called by muse, mutect2, varscan2
- IL6ST | c.2006A>T p.H669L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV100410654; called by muse, mutect2, varscan2
- INPP5D | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1462728006, COSV64039748, COSV64040086; called by muse, mutect2, varscan2
- INTS1 | c.706G>T p.G236W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101247478; called by muse, mutect2, varscan2
- IQSEC2 | c.2362G>C p.V788L (on ENST00000642864 / NM_001111125.3; = p.V583L on NM_015075.2) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV100944750; called by muse, mutect2
- IREB2 | c.2827G>T p.D943Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51925041, COSV99359062; called by muse, mutect2, varscan2
- IRS4 | c.2693G>T p.G898V | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV100929438; called by muse, mutect2, varscan2
- ITGB8 | c.874C>A p.L292I | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99750644; called by muse, mutect2, varscan2
- ITIH2 | c.1873C>A p.L625M | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as COSV100623170; called by muse, mutect2, varscan2
- JHY | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV99912784; called by muse, mutect2, varscan2
- KAT6A | c.736C>G p.P246A | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV99704467; called by muse, mutect2, varscan2
- KCNG1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100856993; called by muse, mutect2, varscan2
- KCNH1 | c.1655C>A p.T552K (on ENST00000271751 / NM_172362.3; = p.T525K on NM_002238.4) | Missense Mutation (SNP) | VAF 71/119 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99657502; called by muse, mutect2, varscan2
- KCNH6 | c.2068C>G p.L690V | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV100120812; called by muse, mutect2
- KCNU1 | c.2632G>C p.G878R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.726); catalogued as COSV101298958; called by muse, mutect2, varscan2
- KEL | c.43A>T p.S15C | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); catalogued as COSV100786876; called by muse, varscan2
- KLF4 | c.1085C>A p.P362Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV101012649; called by muse, mutect2
- KLHDC8A | c.147C>G p.F49L | Missense Mutation (SNP) | VAF 78/133 reads (59%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV100903786, COSV65678134; called by muse, mutect2, varscan2
- KLK2 | c.440C>G p.A147G | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV100319853; called by muse, mutect2, varscan2
- KRT77 | c.726C>A p.S242R | Missense Mutation (SNP) | VAF 66/435 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1461331229, COSV59241272; called by muse, mutect2, varscan2
- KRTAP24-1 | c.686G>C p.R229T | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV100447323, COSV61089636; called by muse, mutect2, varscan2
- KRTAP5-1 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 57/200 reads (29%) | PolyPhen possibly damaging (0.744); catalogued as COSV101192867; called by muse, mutect2, varscan2
- LGR6 | c.1576G>T p.D526Y (on ENST00000367278 / NM_001017403.1; = p.D474Y on NM_021636.3) | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99706127; called by muse, mutect2, varscan2
- LNX1 | c.1484A>T p.K495M (on ENST00000263925 / NM_001126328.3; = p.K399M on NM_032622.2) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.736); catalogued as COSV99819509; called by muse, mutect2, varscan2
- LRFN5 | c.885G>T p.E295D | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs1379859818, COSV53269329, COSV99982625; called by muse, mutect2, varscan2
- LRP1B | c.10627G>T p.G3543C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101253142; called by muse, mutect2, varscan2
- LRP1B | c.8489G>T p.C2830F | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101253143; called by muse, mutect2, varscan2
- LRRC6 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99137752; called by muse, mutect2
- LRRIQ1 | c.3559G>T p.D1187Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.707); catalogued as COSV67838659; called by muse, mutect2
- LRRIQ1 | c.3683C>T p.S1228L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV101279563; called by muse, mutect2, varscan2
- LRRK2 | c.4491G>T p.L1497F | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV100109351; called by muse, mutect2, varscan2
- LRSAM1 | c.771G>T p.E257D | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100031191; called by muse, mutect2, varscan2
- LTBP1 | c.4264T>A p.Y1422N (on ENST00000404816 / NM_206943.4; = p.Y1096N on NM_000627.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99697787; called by muse, mutect2, varscan2
- MAGEA8 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV99674414; called by muse, mutect2, varscan2
- MAGEB16 | c.802A>T p.S268C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101303280; called by muse, mutect2
- MAP3K4 | c.3675-1G>T p.X1225_splice | Splice Site (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100815064; called by muse, mutect2
- MAPK8IP2 | c.1669G>T p.G557C | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV50511729, COSV99151146; called by muse, mutect2, varscan2
- MASP2 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99534043; called by muse, mutect2, varscan2
- MED15 | c.1412C>G p.S471C (on ENST00000263205 / NM_001003891.3; = p.S431C on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99487384, COSV99487719; called by muse, mutect2
- MEGF10 | c.2749G>A p.G917S | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99174729; called by muse, mutect2, varscan2
- MMP16 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV99686214; called by muse, mutect2, varscan2
- MROH2B | c.539A>T p.N180I | Missense Mutation (SNP) | VAF 105/194 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV101270511; called by muse, mutect2, varscan2
- MS4A4A | c.494G>C p.C165S | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV59700858; called by muse, mutect2, varscan2
- MT1A | c.110G>T p.C37F | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99319165; called by muse, mutect2, varscan2
- MT4 | c.30T>A p.S10= | Splice Region (SNP) | VAF 24/85 reads (28%) | catalogued as COSV99533698; called by muse, mutect2, varscan2
- MUC16 | c.42897G>T p.L14299F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.962); catalogued as COSV101109642; called by muse, mutect2, varscan2
- MUC16 | c.38753G>T p.G12918V | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV101198335; called by muse, mutect2, varscan2
- MUC16 | c.19699G>T p.G6567C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.065); catalogued as COSV101198336; called by muse, mutect2, varscan2
- MUC16 | c.10786G>T p.D3596Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as COSV67448504; called by muse, varscan2
- MUC17 | c.4261G>T p.V1421F | Missense Mutation (SNP) | VAF 146/375 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as COSV100071770; called by muse, mutect2, varscan2
- MUC3A | c.7331G>C p.S2444T | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated, low confidence (1); catalogued as rs76539110; called by muse, mutect2, varscan2
- MYT1 | c.1035G>T p.E345D | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV100114019; called by muse, mutect2, varscan2
- NCAPD3 | c.2222G>T p.W741L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV101599337; called by muse, mutect2, varscan2
- NCOA2 | c.3654G>T p.L1218F | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.225); catalogued as COSV99144706; called by muse, mutect2, varscan2
- NCOA2 | c.831A>G p.Q277= | Splice Region (SNP) | VAF 6/62 reads (10%) | catalogued as COSV101475910; called by muse, mutect2
- NDUFAF6 | c.821G>T p.R274M | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV99712610; called by muse, mutect2, varscan2
- NEB | c.7094G>T p.G2365V | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50816471, COSV99415468; called by muse, mutect2, varscan2
- NETO1 | c.1313C>A p.S438Y | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100198257; called by muse, mutect2, varscan2
- NFATC4 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.306); catalogued as COSV99144455; called by muse, mutect2, varscan2
- NID2 | c.3023C>A p.S1008* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99356009; called by muse, mutect2, varscan2
- NIPSNAP2 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 22/94 reads (23%) | catalogued as COSV100436632, COSV59051565; called by muse, mutect2, varscan2
- NLRP14 | c.1265C>A p.A422D | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100204611; called by muse, mutect2, varscan2
- NLRP3 | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV60229064; called by muse, mutect2, varscan2
- NLRP9 | c.773G>T p.S258I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100242636; called by muse, mutect2, varscan2
- NOL9 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs139155763, COSV100891412; called by muse, mutect2, varscan2
- NPHS1 | c.2756C>T p.T919I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV100799626; called by muse, mutect2, varscan2
- NRSN1 | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101027211, COSV104429082; called by muse, mutect2, varscan2
- NRXN3 | c.1834C>A p.R612S (on ENST00000335750 / NM_001330195.2; = p.R239S on NM_004796.6) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100201021; called by muse, mutect2, varscan2
- NTRK2 | c.2127C>A p.V709= (on ENST00000323115 / NM_001369534.1; = p.V725= on NM_006180.6 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 25/108 reads (23%) | catalogued as COSV99451351, COSV99452626; called by muse, mutect2, varscan2
- NUTM2G | c.218C>A p.P73Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV100672586; called by muse, mutect2, varscan2
- OPHN1 | c.851G>T p.W284L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100830229; called by muse, mutect2, varscan2
- OR1L4 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99413788; called by muse, mutect2, varscan2
- OR2A2 | c.831C>A p.H277Q | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV101286619; called by muse, mutect2, varscan2
- OR2W1 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs922264436, COSV101013897; called by muse, mutect2, varscan2
- OR4K17 | c.384del p.K128Nfs*6 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as COSV59647228; called by pindel, varscan2
- OR4K2 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as COSV100064150; called by muse, mutect2
- OR51A4 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV100985188; called by muse, mutect2, varscan2
- OR51B2 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.279); catalogued as COSV100173284; called by muse, varscan2
- OR51E2 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV101211317; called by muse, mutect2, varscan2
- OR51M1 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV100150142, COSV100150337, COSV60785787; called by muse, mutect2, varscan2
- OR5M3 | c.193T>A p.S65T | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100392316; called by muse, mutect2, varscan2
- OR5R1 | c.24T>A p.Y8* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as COSV100393279; called by muse, mutect2, varscan2
- OR6B2 | c.111T>A p.F37L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99401195; called by muse, mutect2, varscan2
- OR6M1 | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100484019; called by muse, mutect2, varscan2
- OR8A1 | c.885A>T p.E295D | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV99420343; called by muse, mutect2, varscan2
- OR8D1 | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100766538, COSV63441779; called by muse, mutect2
- OR8H2 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV57946331; called by muse, mutect2, varscan2
- OVCH1 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.444); catalogued as COSV99758846; called by muse, mutect2, varscan2
- OXR1 | c.1109C>A p.S370Y (on ENST00000442977 / NM_001198532.1; = p.S369Y on NM_018002.3) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100366793; called by muse, mutect2, varscan2
- PAK4 | c.1736C>A p.A579D | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100426383; called by muse, mutect2, varscan2
- PCDH10 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99993059; called by muse, mutect2, varscan2
- PCDH18 | c.1603C>A p.H535N | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV100787063, COSV61267409; called by muse, mutect2, varscan2
- PDCD1 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100545313, COSV100545353; called by muse, mutect2, varscan2
- PDCD11 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 37/113 reads (33%) | catalogued as COSV100874244; called by muse, mutect2
- PDZD4 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99381075; called by muse, mutect2, varscan2
- PEG3 | c.319C>G p.R107G | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as COSV55631206, COSV99687501; called by muse, mutect2, varscan2
- PGK2 | c.416A>T p.K139M | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100505348; called by muse, mutect2, varscan2
- PHACTR4 | c.17-1G>A p.X6_splice (on ENST00000373839 / NM_001350159.2; = p.X16_splice on NM_023923.4) | Splice Site (SNP) | VAF 26/54 reads (48%) | catalogued as COSV100868402; called by muse, mutect2
- PHF2 | c.3109G>T p.A1037S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV100823039; called by muse, mutect2, varscan2
- PI4KB | c.1013G>T p.R338L (on ENST00000368873 / NM_001369623.1; = p.R350L on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/153 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV99649327; called by muse, mutect2, varscan2
- PKD1 | c.4651C>G p.L1551V | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV99237243; called by muse, mutect2, varscan2
- PKHD1 | c.8141G>T p.R2714L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61878560; called by muse, mutect2, varscan2
- PLA2G4D | c.1220G>A p.S407N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.636); catalogued as rs542084472, COSV99299300; called by muse, mutect2, varscan2
- PLAU | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.892); catalogued as COSV65641881; called by muse, mutect2, varscan2
- PLCB1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV62056013; called by muse, mutect2, varscan2
- PLCL1 | c.2327C>A p.P776H | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101406771; called by muse, mutect2, varscan2
- PLIN1 | c.1131G>T p.K377N | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100261422; called by muse, mutect2
- PLPPR4 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100926707; called by muse, mutect2, varscan2
- PLXNB3 | c.848G>A p.C283Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737150; called by muse, mutect2, varscan2
- POF1B | c.680G>C p.G227A | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.251); catalogued as COSV99426070; called by muse, mutect2, varscan2
- PPP1R16B | c.321+1G>T p.X107_splice | Splice Site (SNP) | VAF 41/187 reads (22%) | catalogued as COSV100239024; called by muse, mutect2, varscan2
- PRUNE2 | c.3667G>T p.V1223F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs765487230, COSV100944246; called by muse, mutect2, varscan2
- PTCHD3 | c.817C>A p.Q273K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as COSV101438835; called by muse, mutect2, varscan2
- PTPRH | c.2579G>T p.R860L | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV54748094; called by muse, varscan2
- PXDNL | c.2459C>A p.A820E | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100681615, COSV62480734, COSV62500084; called by muse, mutect2, varscan2
- RALYL | c.119C>A p.A40D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs895571423, COSV72817596, COSV72824705; called by muse, mutect2, varscan2
- RANBP2 | c.5044G>T p.A1682S | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as COSV99311334; called by muse, varscan2
- RASL12 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99584762; called by muse, mutect2
- RECK | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs189825349, COSV65034673, COSV65035887; called by mutect2, varscan2
- RESF1 | c.903G>T p.L301F | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100440113; called by muse, mutect2, varscan2
- RGS21 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101313984; called by muse, mutect2, varscan2
- RIMBP2 | c.2614G>T p.E872* | Nonsense Mutation (SNP) | VAF 21/136 reads (15%) | catalogued as COSV99898480; called by muse, mutect2, varscan2
- RIMS2 | c.2846G>T p.R949I (on ENST00000666250 / NM_001348490.2; = p.R757I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV51687844; called by muse, mutect2, varscan2
- RIMS4 | c.602G>T p.W201L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV100865074; called by muse, mutect2
- RTKN2 | c.1041G>T p.M347I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.025); catalogued as COSV100189219; called by muse, mutect2, varscan2
- RXRG | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 74/127 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100717249; called by muse, mutect2, varscan2
- RYR1 | c.3425G>A p.W1142* | Nonsense Mutation (SNP) | VAF 20/95 reads (21%) | catalogued as COSV100614640; called by muse, mutect2, varscan2
- RYR2 | c.13729A>G p.I4577V | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100768239; called by muse, mutect2, varscan2
- SCAF8 | c.1940C>T p.P647L | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV100781293; called by muse, mutect2, varscan2
- SCAMP5 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.019); catalogued as COSV100723788; called by muse, mutect2, varscan2
- SCD5 | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs746393792, COSV99262264; called by muse, mutect2, varscan2
- SCUBE3 | c.2014T>G p.C672G | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99233988; called by muse, mutect2, varscan2
- SEL1L | c.1493G>T p.G498V | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158677678, COSV100377674; called by muse, mutect2, varscan2
- SERINC1 | c.939G>A p.W313* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as COSV100305060; called by muse, mutect2, varscan2
- SERPINA3 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV101261614, COSV67586692, COSV67586722; called by muse, mutect2, varscan2
- SERPINA9 | c.55T>C p.Y19H | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100097925; called by muse, mutect2, varscan2
- SERPINB6 | c.70G>T p.A24S (on ENST00000612421 / NM_001271823.2; = p.A5S on NM_004568.6) | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100177407; called by muse, mutect2, varscan2
- SH3RF1 | c.2621A>T p.N874I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99498684; called by muse, mutect2, varscan2
- SIGLEC8 | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 27/115 reads (23%) | catalogued as COSV58474549; called by muse, mutect2, varscan2
- SIRPD | c.480C>A p.H160Q | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV101064853; called by muse, mutect2, varscan2
- SLC12A3 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV99343860; called by muse, mutect2, varscan2
- SLC15A1 | c.715T>G p.C239G | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100918180; called by muse, varscan2
- SLC22A2 | c.1190C>A p.T397N | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100870932, COSV65265654; called by muse, mutect2, varscan2
- SLC25A12 | c.1193G>T p.G398V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs761361585, COSV99784708; called by muse, mutect2, varscan2
- SLC25A12 | c.1192G>T p.G398W | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99784709; called by muse, mutect2, varscan2
- SLC27A6 | c.749C>A p.A250D | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.731); catalogued as COSV52481757, COSV99322219; called by muse, mutect2, varscan2
- SLC9A6 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 47/332 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); catalogued as COSV100857852; called by muse, mutect2, varscan2
- SLIT1 | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.382); catalogued as COSV99820673; called by muse, mutect2, varscan2
- SNAPC3 | c.879G>T p.M293I | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV101070258; called by muse, mutect2, varscan2
- SNRPN | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.284); catalogued as COSV100577907; called by muse, mutect2, varscan2
- SNX12 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV99339871; called by muse, mutect2, varscan2
- SPATA31D1 | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.475); catalogued as rs367678939, COSV100782508; called by muse, mutect2, varscan2
- SPHKAP | c.3158C>T p.S1053F | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV60876142; called by muse, mutect2, varscan2
- SPHKAP | c.2732C>A p.P911H | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100763740, COSV100764708; called by muse, mutect2, varscan2
- SPRY3 | c.200G>T p.S67I | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.588); catalogued as COSV100249196; called by muse, mutect2, varscan2
- SQLE | c.1088A>C p.K363T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as COSV99772120; called by muse, mutect2, varscan2
- SRD5A2 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as COSV51873520; called by muse, mutect2, varscan2
- SREBF1 | c.1520T>C p.L507P | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV55420056; called by muse, mutect2, varscan2
- ST6GAL2 | c.155T>A p.L52Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | PolyPhen probably damaging (0.921); catalogued as COSV100867690; called by muse, mutect2, varscan2
- STAU2 | c.475G>T p.G159W (on ENST00000524300 / NM_001164380.2; = p.G127W on NM_014393.2) | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100869011; called by muse, mutect2, varscan2
- SYCP2L | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51649573, COSV99304708; called by muse, mutect2, varscan2
- SYP | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99602739; called by muse, mutect2, varscan2
- SYT4 | c.263C>A p.P88Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.216); catalogued as COSV99673344; called by muse, mutect2, varscan2
- TBX22 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100960631; called by muse, mutect2, varscan2
- TCTE1 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV101025317; called by muse, mutect2, varscan2
- TCTE1 | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV101025319, COSV65255544; called by muse, mutect2, varscan2
- TEP1 | c.1267-1G>T p.X423_splice | Splice Site (SNP) | VAF 29/114 reads (25%) | catalogued as COSV99401729; called by muse, mutect2, varscan2
- TET3 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.413); catalogued as COSV99996195; called by muse, mutect2, varscan2
- TFR2 | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV99774356; called by muse, mutect2, varscan2
- TGM6 | c.1833+1G>T p.X611_splice | Splice Site (SNP) | VAF 11/24 reads (46%) | catalogued as rs978685218, COSV99171684; called by muse, mutect2, varscan2
- THBS2 | c.2685del p.C896Vfs*105 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as COSV64677442; called by mutect2, pindel*
- THSD4 | c.600G>C p.R200S | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.06); catalogued as COSV99964611; called by muse, mutect2
- TJP1 | c.4666G>T p.E1556* | Nonsense Mutation (SNP) | VAF 19/141 reads (13%) | catalogued as COSV100632363; called by muse, mutect2, varscan2
- TLL1 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV50337648, COSV99286307; called by muse, varscan2
- TM6SF2 | c.805-2A>G p.X269_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99363648; called by muse, mutect2, varscan2
- TMEM169 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.033); catalogued as COSV99824361; called by muse, mutect2, varscan2
- TMEM174 | c.232C>A p.L78M | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99703719; called by muse, mutect2, varscan2
- TMPPE | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV100256969; called by muse, mutect2, varscan2
- TMPRSS11E | c.1181G>T p.W394L | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100542240; called by muse, mutect2, varscan2
- TNNI3K | c.2284G>T p.A762S | Missense Mutation (SNP) | VAF 69/107 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.371); catalogued as COSV99631111; called by muse, mutect2, varscan2
- TOGARAM1 | c.4282-1G>T p.X1428_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100817838; called by muse, mutect2, varscan2
- TPO | c.2450C>A p.T817N | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as rs1333447684, COSV100219820; called by muse, mutect2, varscan2
- TPX2 | c.436G>C p.A146P | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100301536; called by muse, mutect2, varscan2
- TRAPPC8 | c.1930A>T p.R644* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99350603; called by muse, mutect2, varscan2
- TREM1 | c.393G>T p.L131F | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99776075; called by muse, mutect2, varscan2
- TRIM5 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100000053; called by muse, mutect2, varscan2
- TRIM51 | c.571C>A p.H191N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as COSV55266844, COSV99792173; called by muse, mutect2, varscan2
- TRIM51 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs776737248, COSV99792176; called by muse, mutect2, varscan2
- TRIM63 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 66/130 reads (51%) | catalogued as COSV100958130; called by muse, mutect2, varscan2
- TTC7A | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV55408251, COSV55414110; called by muse, mutect2, varscan2
- TTN | c.17717C>A p.T5906K (on ENST00000591111; = p.T4979K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | PolyPhen benign (0.001); catalogued as COSV100596181; called by muse, mutect2, varscan2
- UGT2B15 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as rs1376045245, COSV100592225; called by muse, mutect2, varscan2
- UNC13A | c.3406G>T p.D1136Y | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV53196907, COSV99407446; called by muse, mutect2, varscan2
- UNC80 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV55896681, COSV55902842; called by muse, mutect2, varscan2
- USP26 | c.1224A>T p.K408N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV100896553; called by muse, mutect2, varscan2
- VAMP7 | c.29G>T p.R10M | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99387722, COSV99387785; called by muse, mutect2, varscan2
- VN1R2 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as rs752929083, COSV100447791; called by muse, mutect2, varscan2
- WAS | c.1033G>C p.V345L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1557007154, COSV100939437; called by muse, mutect2, varscan2
- XXYLT1 | c.572A>T p.H191L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100118117; called by muse, mutect2, varscan2
- XYLT1 | c.1674G>C p.K558N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV99760446, COSV99763331; called by muse, mutect2, varscan2
- ZBTB39 | c.1169A>G p.H390R | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1451659232, COSV100267917; called by muse, mutect2, varscan2
- ZBTB41 | c.830C>G p.S277* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV100962863; called by muse, mutect2
- ZBTB7C | c.1678G>T p.G560W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.585); catalogued as COSV100134269, COSV59688243; called by muse, mutect2, varscan2
- ZC3H15 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs374300681; called by muse, mutect2, varscan2
- ZC3H18 | c.1736A>G p.Y579C | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV99963862; called by muse, mutect2, varscan2
- ZEB1 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100313704, COSV58042788; called by muse, mutect2, varscan2
- ZER1 | c.1064A>T p.Q355L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99401856, COSV99401861; called by muse, mutect2, varscan2
- ZFHX3 | c.2162G>T p.C721F | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99195377; called by muse, mutect2, varscan2
- ZFHX4 | c.4919C>A p.A1640E | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.193); catalogued as rs557822142, COSV99257007; called by muse, mutect2, varscan2
- ZHX1 | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 169/242 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763656006, COSV99933498; called by muse, mutect2, varscan2
- ZNF200 | c.770G>T p.C257F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101205204; called by muse, mutect2, varscan2
- ZNF257 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV101448031; called by muse, mutect2, varscan2
- ZNF35 | c.383T>C p.I128T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99939971; called by muse, mutect2, varscan2
- ZNF423 | c.1199G>T p.R400L (on ENST00000563137 / NM_001379286.1; = p.R392L on NM_015069.4) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV52179386, COSV99280040; called by muse, mutect2
- ZNF468 | c.457A>T p.I153L | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99700359; called by muse, mutect2, varscan2
- ZNF513 | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1267972195; called by muse, mutect2
- ZNF536 | c.1281C>A p.Y427* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as COSV100834727; called by muse, mutect2, varscan2
- ZNF536 | c.3283G>A p.A1095T | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs774780132, COSV100834728; called by muse, mutect2, varscan2
- ZNF549 | c.1705C>T p.R569C (on ENST00000376233 / NM_001199295.2; = p.R556C on NM_153263.2) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as rs180734719, COSV53727875; called by muse, mutect2, varscan2
- ZNF683 | c.1413G>T p.W471C (on ENST00000403843; = p.W451C on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100853660, COSV62874843; called by muse, mutect2
- ZNF683 | c.227G>T p.C76F | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV100853661; called by muse, mutect2, varscan2
- ZNF700 | c.1312G>T p.G438W | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs879218245; called by muse, varscan2
- ZNF831 | c.2402G>A p.W801* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100925790, COSV100926167; called by muse, mutect2, varscan2
- ZNF831 | c.3304G>T p.E1102* | Nonsense Mutation (SNP) | VAF 19/88 reads (22%) | catalogued as COSV100925791; called by muse, mutect2, varscan2
- ZNF835 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV73379803; called by muse, mutect2, varscan2
- ACACB | c.2701dup p.S901Ffs*17 | Frame Shift Ins (INS) | VAF 33/135 reads (24%) | called by mutect2, pindel, varscan2
- ARSI | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2
- CCL23 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); called by muse, mutect2
- DNHD1 | c.11565del p.W3855Cfs*7 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel*, varscan2
- EYA4 | c.1423dup p.T475Nfs*8 (on ENST00000531901 / NM_001301013.1; = p.T469Nfs*8 on NM_004100.5) | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- FOLH1B | n.1771-1G>A | Splice Site (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2
- GUCY2C | c.2906T>A p.I969K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.574); called by muse, mutect2
- IGHV1OR21-1 | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 48/674 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2
- IGHV3-16 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGKV6-21 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- KRT4 | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- LRRCC1 | c.830_831del p.C277Sfs*4 | Frame Shift Del (DEL) | VAF 52/120 reads (43%) | called by pindel, varscan2
- MRC1 | c.2916G>T p.E972D | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLRP11 | c.434dup p.N145Kfs*30 | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- OLFM1 | c.1039T>G p.Y347D (on ENST00000371793 / NM_001282611.2; = p.Y329D on NM_014279.5) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR10A4 | c.516dup p.N173Qfs*9 | Frame Shift Ins (INS) | VAF 25/90 reads (28%) | called by mutect2, pindel, varscan2
- PDIA4 | c.389G>T p.S130I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- SAXO1 | c.34dup p.C12Lfs*15 | Frame Shift Ins (INS) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- SFTPB | c.268-12_275del p.X90_splice | Splice Site (DEL) | VAF 20/191 reads (10%) | called by mutect2, pindel
- SRGAP3 | c.731dup p.L244Ffs*18 | Frame Shift Ins (INS) | VAF 33/100 reads (33%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.952G>T p.V318F | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TRBC2 | c.91T>G p.C31G | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ZNF334 | c.86del p.P29Lfs*10 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | called by mutect2, pindel, varscan2
- ZNF705A | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.05); called by mutect2, varscan2
- ABCG5 | c.1524C>A p.A508= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV99575172; called by muse, varscan2
- ABHD14B | c.165C>T p.H55= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99865284; called by muse, mutect2, varscan2
- ACACB | c.435C>A p.G145= | Silent (SNP) | VAF 35/216 reads (16%) | catalogued as COSV100622383; called by muse, mutect2, varscan2
- ACO2 | c.633C>T p.A211= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs1049859; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAMTS2 | c.2949C>A p.P983= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV99281043; called by muse, mutect2, varscan2
- ADAMTS7 | c.3021C>T p.G1007= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV101183018; called by muse, varscan2
- APBA2 | c.294C>A p.T98= | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as COSV101381933; called by muse, mutect2, varscan2
- APCDD1 | c.1488G>T p.L496= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as rs763054541, COSV100789902; called by muse, mutect2, varscan2
- ARG2 | c.501C>A p.L167= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV99937379; called by muse, mutect2, varscan2
- ARHGAP20 | c.1125T>C p.N375= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as rs1339938702, COSV99503195; called by muse, mutect2
- ATP12A | c.1080G>A p.S360= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs759783098, COSV54521639; called by muse, mutect2, varscan2
- BRIP1 | c.618G>A p.S206= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs367614726; ClinVar: benign / likely benign; called by mutect2, varscan2
- C3AR1 | c.291C>A p.L97= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99368140; called by muse, mutect2, varscan2
- CEMP1 | c.298C>T p.L100= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99565636; called by muse, mutect2, varscan2
- CHST6 | c.1077G>T p.R359= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs772588909, COSV60002224; called by muse, mutect2, varscan2
- CNTNAP5 | c.2874C>A p.G958= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV101443088; called by muse, mutect2, varscan2
- COL4A6 | c.249C>A p.G83= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as rs1287378260, COSV100563427; called by muse, mutect2, varscan2
- DBF4B | c.69G>T p.R23= | Silent (SNP) | VAF 40/377 reads (11%) | catalogued as COSV100154311; called by muse, mutect2, varscan2
- DCAF12L2 | c.1059G>C p.V353= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as COSV100758471; called by muse, varscan2
- DCLK3 | c.147A>G p.K49= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV101373881; called by muse, mutect2, varscan2
- DCSTAMP | c.150C>A p.A50= | Silent (SNP) | VAF 180/298 reads (60%) | catalogued as COSV99886108; called by muse, mutect2, varscan2
- DDR2 | c.39G>T p.L13= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as COSV100906205; called by muse, mutect2, varscan2
- DHRS7 | c.297T>C p.N99= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99381496; called by muse, mutect2, varscan2
- DHX58 | c.1599G>T p.R533= | Silent (SNP) | VAF 59/131 reads (45%) | catalogued as COSV99288040; called by muse, mutect2, varscan2
- DIP2C | c.2472G>T p.R824= | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as COSV55164933, COSV99790206; called by muse, mutect2, varscan2
- DPYSL5 | c.1131C>T p.T377= | Silent (SNP) | VAF 65/166 reads (39%) | catalogued as COSV99981818; called by muse, mutect2, varscan2
- DSC3 | c.2379G>T p.R793= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100844531, COSV100844773; called by muse, mutect2, varscan2
- EFCAB3 | c.529T>C p.L177= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as rs771065066, COSV100540053; called by muse, mutect2, varscan2
- EGF | c.489A>T p.V163= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99490516; called by muse, varscan2
- FCGBP | c.1065G>A p.E355= | Silent (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- FGA | c.2283T>C p.T761= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV100120041, COSV57397077; called by muse, mutect2, varscan2
- FLNA | c.3456C>T p.A1152= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV61038875; called by muse, mutect2, varscan2
- GDF10 | c.1413C>T p.S471= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as rs782253093; called by muse, mutect2, varscan2
- GHSR | c.675C>A p.V225= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV99576707; called by muse, mutect2, varscan2
- GNRHR | c.936C>A p.A312= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as COSV99891998; called by muse, mutect2, varscan2
- GPR101 | c.504C>T p.Y168= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs755317343, COSV53238432; called by muse, mutect2, varscan2
- GPR158 | c.1371G>T p.T457= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs1175352427, COSV100892907, COSV66264628; called by muse, mutect2, varscan2
- GPR89B | c.1290C>T p.F430= | Silent (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- GRM1 | c.489C>A p.G163= | Silent (SNP) | VAF 43/139 reads (31%) | catalogued as COSV51366135; called by muse, mutect2, varscan2
- GRM8 | c.1557G>T p.P519= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV100280975, COSV58853050; called by muse, mutect2, varscan2
- HAS3 | c.861G>A p.L287= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs1161310619, COSV54705903; called by muse, mutect2, varscan2
- HNF4G | c.870G>T p.L290= (on ENST00000354370 / NM_001330561.2; = p.L337= on NM_004133.5) | Silent (SNP) | VAF 113/189 reads (60%) | catalogued as COSV100584079; called by muse, mutect2, varscan2
- ITGA8 | c.2683C>A p.R895= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs752710916, COSV100958899, COSV65227780; called by muse, mutect2, varscan2
- KDM5C | c.2646C>T p.A882= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100948812; called by muse, mutect2
- KEL | c.9T>A p.G3= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as COSV100786877, COSV62338299; called by muse, varscan2
- KIAA1549L | c.1440A>T p.L480= (on ENST00000321505; = p.L777= on NM_012194.3) | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV99682692; called by muse, mutect2, varscan2
- KRTAP13-3 | c.147T>A p.G49= | Silent (SNP) | VAF 49/90 reads (54%) | catalogued as COSV100481712; called by muse, mutect2, varscan2
- LGR5 | c.2127C>A p.S709= | Silent (SNP) | VAF 73/218 reads (33%) | catalogued as COSV57011221, COSV99877549; called by muse, mutect2, varscan2
- LMBR1 | c.1014C>T p.A338= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs770221989, COSV100626548; called by muse, mutect2, varscan2
- LNX1 | c.792C>T p.Y264= (on ENST00000263925 / NM_001126328.3; = p.Y168= on NM_032622.2) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99819513; called by muse, mutect2, varscan2
- LRIG1 | c.2820T>C p.C940= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs1461621346, COSV99833277; called by muse, mutect2, varscan2
- MAGEC1 | c.2220C>A p.L740= | Silent (SNP) | VAF 36/197 reads (18%) | catalogued as COSV53575009, COSV99594933; called by muse, mutect2, varscan2
- MAGEL2 | c.2091C>A p.P697= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100045753; called by muse, mutect2, varscan2
- MARK1 | c.2091G>T p.P697= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV65072778; called by muse, mutect2, varscan2
- MCPH1 | c.1134G>A p.R378= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100765312; called by muse, mutect2, varscan2
- MICAL3 | c.4215G>T p.R1405= | Silent (SNP) | VAF 48/164 reads (29%) | catalogued as COSV101490814; called by muse, mutect2, varscan2
- MKRN3 | c.906T>G p.A302= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100090785; called by muse, mutect2, varscan2
- MMP10 | c.1134G>A p.L378= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV99666373; called by muse, mutect2, varscan2
- MPZL1 | c.792G>T p.A264= | Silent (SNP) | VAF 47/72 reads (65%) | catalogued as rs200004895, COSV100850319; called by muse, mutect2, varscan2
- MROH5 | c.2166C>A p.V722= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as rs1253166611, COSV101435890; called by muse, mutect2, varscan2
- MS4A10 | c.81C>G p.P27= | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as COSV100382214; called by muse, mutect2, varscan2
- MS4A3 | c.258C>T p.T86= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as COSV99614538, COSV99614724; called by muse, mutect2, varscan2
- MYO18B | c.2001C>A p.T667= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV100122727; called by muse, mutect2, varscan2
- MYO3B | c.333G>T p.G111= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100509265; called by muse, mutect2, varscan2
- NLRP6 | c.1359C>T p.V453= | Silent (SNP) | VAF 68/212 reads (32%) | catalogued as rs374795710; called by muse, mutect2, varscan2
- OR2B11 | c.684A>T p.A228= | Silent (SNP) | VAF 72/123 reads (59%) | catalogued as COSV100275315; called by muse, mutect2, varscan2
- OR51E1 | c.15C>A p.P5= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV67810758; called by muse, mutect2, varscan2
- OR52A5 | c.456C>G p.L152= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100263306; called by muse, mutect2, varscan2
- OR5P2 | c.402A>T p.T134= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV100271200; called by muse, mutect2, varscan2
- OR6M1 | c.243C>A p.A81= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV100484018; called by muse, mutect2, varscan2
- OR7E24 | c.903C>A p.P301= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV101509636; called by muse, mutect2, varscan2
- OXER1 | c.228G>T p.G76= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs1297282148, COSV99685255; called by muse, mutect2, varscan2
- PADI3 | c.456G>T p.V152= | Silent (SNP) | VAF 55/148 reads (37%) | catalogued as COSV64934595; called by muse, mutect2, varscan2
- PAX2 | c.153C>A p.P51= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV62291753; called by muse, mutect2, varscan2
- PCDHB6 | c.1470G>A p.P490= | Silent (SNP) | VAF 91/251 reads (36%) | catalogued as rs782062278, COSV50702389, COSV99170684; called by muse, mutect2, varscan2
- PHYHIPL | c.1032C>G p.T344= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV53244576, COSV53245758; called by muse, mutect2, varscan2
- POMT1 | c.87C>T p.S29= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs777011685, COSV100260865; called by muse, mutect2, varscan2
- RADIL | c.912G>T p.P304= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV101271275; called by muse, mutect2, varscan2
- RASA3 | c.933G>T p.A311= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV100479897; called by muse, mutect2, varscan2
- RP1 | c.1113A>T p.G371= | Silent (SNP) | VAF 35/55 reads (64%) | catalogued as COSV99606389; called by muse, mutect2, varscan2
- RPS7 | c.120C>G p.L40= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100513898; called by muse, mutect2, varscan2
- SELP | c.2094A>T p.A698= | Silent (SNP) | VAF 258/419 reads (62%) | catalogued as COSV99739099; called by muse, mutect2, varscan2
- SERPINA10 | c.84G>A p.S28= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs758769939, COSV56229108; called by muse, mutect2, varscan2
- SERPINE3 | c.333G>T p.L111= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV101246352; called by muse, mutect2, varscan2
- SIGLEC10 | c.900C>A p.P300= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100218521; called by muse, mutect2, varscan2
- SIGLEC14 | c.1161C>G p.P387= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV99707162; called by muse, mutect2, varscan2
- SLC24A4 | c.498G>A p.G166= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV100104342; called by muse, mutect2
- SMARCA1 | c.1254G>T p.G418= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100946366; called by muse, mutect2, varscan2
- SREBF1 | c.1521G>T p.L507= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99888352; called by muse, mutect2, varscan2
- SYCE1 | c.210C>A p.A70= (on ENST00000343131 / NM_001143764.3; = p.A34= on NM_130784.3) | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100385635, COSV100385707; called by muse, mutect2, varscan2
- SYT16 | c.1506T>A p.S502= | Silent (SNP) | VAF 40/134 reads (30%) | catalogued as COSV101413518; called by muse, mutect2, varscan2
- TAS2R1 | c.297C>A p.L99= | Silent (SNP) | VAF 37/50 reads (74%) | catalogued as COSV66779216; called by muse, mutect2, varscan2
- TAS2R41 | c.402G>T p.L134= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV101281471; called by muse, mutect2, varscan2
- TBC1D21 | c.450C>A p.L150= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100311201; called by muse, mutect2
- TBCCD1 | c.1365A>C p.T455= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV100111815; called by muse, mutect2, varscan2
- TCN1 | c.210C>A p.T70= | Silent (SNP) | VAF 22/135 reads (16%) | catalogued as rs1227081866, COSV99953111; called by muse, mutect2, varscan2
- THSD1 | c.402G>A p.L134= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV99318722, COSV99318754; called by muse, mutect2, varscan2
- TLN2 | c.3744A>T p.A1248= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV100168118; called by muse, mutect2, varscan2
- TMEM63B | c.483G>T p.L161= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV99441083; called by muse, mutect2, varscan2
- TMPRSS11A | c.198C>T p.F66= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs572862011, COSV58357272; called by muse, mutect2, varscan2
- TNR | c.693C>T p.S231= | Silent (SNP) | VAF 31/233 reads (13%) | catalogued as rs775081401, COSV54874573; called by muse, mutect2, varscan2
- TRPC5 | c.693C>T p.S231= | Silent (SNP) | VAF 34/225 reads (15%) | catalogued as COSV99459460; called by muse, mutect2, varscan2
- TRPM6 | c.3585T>C p.S1195= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV100665483; called by muse, mutect2, varscan2
- TRPV6 | c.1548C>A p.G516= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV100844140; called by muse, mutect2, varscan2
- UCHL1 | c.504G>T p.V168= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99448956; called by muse, mutect2, varscan2
- UMOD | c.153C>A p.T51= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100208027; called by muse, mutect2, varscan2
- UNC45B | c.2103C>A p.I701= | Silent (SNP) | VAF 75/127 reads (59%) | catalogued as rs1344831821, COSV99268253; called by muse, mutect2, varscan2
- USP51 | c.1632A>T p.P544= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV101540646, COSV72351511; called by muse, mutect2, varscan2
- VPS26B | c.444A>C p.V148= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99844812; called by muse, mutect2, varscan2
- ZEB2 | c.2568A>T p.S856= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100355092; called by muse, mutect2, varscan2
- ZFHX4 | c.2064G>T p.R688= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV51492146, COSV99257002; called by muse, mutect2
- ZKSCAN7 | c.99C>T p.N33= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV99837447; called by muse, mutect2, varscan2
- ZNF479 | c.267G>T p.T89= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV100482521, COSV100483164, COSV58639204; called by muse, mutect2, varscan2
- ZNF577 | c.492G>C p.G164= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV100030804; called by muse, mutect2, varscan2
- ZNF831 | c.579G>T p.T193= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as COSV100925788; called by muse, mutect2, varscan2
- ZNF862 | c.1923G>A p.G641= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99783235; called by muse, mutect2, varscan2
- ZSCAN18 | c.1410G>A p.A470= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs765241107, COSV99559117; called by muse, mutect2, varscan2
- AC103796.1 | n.148-24894C>A | Intron (SNP) | VAF 20/86 reads (23%) | catalogued as COSV100151149; called by muse, mutect2, varscan2
- AL590867.2 | n.313C>T | RNA (SNP) | VAF 22/179 reads (12%) | called by muse, mutect2, varscan2
- COL5A1 | c.654+7209G>T | Intron (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100879576; called by muse, mutect2, varscan2
- CR1 | c.487+12101C>A | Intron (SNP) | VAF 50/174 reads (29%) | catalogued as rs905671575, COSV100887409; called by muse, mutect2, varscan2
- CR1 | c.487+12102C>A | Intron (SNP) | VAF 49/174 reads (28%) | catalogued as rs1283259320, COSV100887410; called by muse, mutect2, varscan2
- MAGEA5 | n.326T>A | RNA (SNP) | VAF 21/121 reads (17%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85474G>T | Intron (SNP) | VAF 8/23 reads (35%) | catalogued as COSV72283505, COSV72283812; called by muse, mutect2, varscan2
- NGB | c.*275G>T | 3'UTR (SNP) | VAF 12/64 reads (19%) | catalogued as rs766488042, COSV100030023; called by muse, mutect2, varscan2
- PPP2R3A | c.1996-3668G>A | Intron (SNP) | VAF 11/73 reads (15%) | catalogued as rs148564742; called by muse, mutect2, varscan2
- PREX2 | c.2716-2833G>T | Intron (SNP) | VAF 8/150 reads (5%) | catalogued as COSV99906478; called by muse, mutect2
- TMEM167B | chr1:109100526 G>T | 3'Flank (SNP) | VAF 26/49 reads (53%) | catalogued as rs773186764; called by muse, mutect2, varscan2
- TSPAN32 | c.-47C>A | 5'UTR (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99478014; called by muse, mutect2, varscan2
- TTN | c.10361-4230T>C | Intron (SNP) | VAF 25/86 reads (29%) | catalogued as COSV100596182; called by muse, mutect2, varscan2
- VPS11 | c.-150C>G | 5'UTR (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100333549; called by muse, mutect2, varscan2
